Somatic mutation profile of tumor specimen TCGA-J8-A3YF-01A (aliquot TCGA-J8-A3YF-01A-12D-A23M-08) from TCGA case TCGA-J8-A3YF, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 83.9 years (30,661 days).
Specimen TCGA-J8-A3YF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35db91ce-4197-4924-81ef-d6cf1be42fc2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J8-A3YF-10A (Blood Derived Normal), aliquot TCGA-J8-A3YF-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a5416c6-f9de-426d-a1dd-c5c1bb416081

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 18, Silent 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CAP2 | c.759A>T p.K253N | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV100012565; called by muse, mutect2, varscan2
- CRACD | c.2347G>A p.A783T | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0.063); catalogued as COSV51715979; called by muse, mutect2, varscan2
- DDX42 | c.907A>G p.K303E | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63790467; called by muse, mutect2, varscan2
- DPYSL5 | c.1498G>A p.V500M | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.043); catalogued as rs773526134, COSV56514434; called by muse, mutect2, varscan2
- EYA3 | c.20T>A p.L7* | Nonsense Mutation (SNP) | VAF 27/95 reads (28%) | catalogued as COSV100870257; called by muse, mutect2, varscan2
- GNPAT | c.776T>G p.L259R | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100791642; called by muse, mutect2, varscan2
- KCNG1 | c.1478G>A p.S493N | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.182); catalogued as COSV65369442; called by muse, mutect2, varscan2
- MAGI1 | c.3235A>G p.I1079V (on ENST00000402939 / NM_001033057.2; = p.I1108V on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/205 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.07); catalogued as COSV100441463; called by muse, mutect2, varscan2
- OR51I1 | c.85G>T p.V29F | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV100971437; called by muse, mutect2, varscan2
- PACRGL | c.588T>A p.H196Q | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99764217; called by muse, mutect2, varscan2
- RNMT | c.506T>A p.I169N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100054688; called by muse, mutect2, varscan2
- SPG21 | c.797A>G p.N266S | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as rs764559344, COSV99200193; called by muse, mutect2, varscan2
- TEX15 | c.7350T>A p.D2450E (on ENST00000256246; = p.D2833E on NM_001350162.2) | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as COSV99821489; called by muse, mutect2, varscan2
- TULP2 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs747614879, COSV55479885; called by muse, mutect2, varscan2
- UBXN2B | c.527A>G p.K176R | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.306); catalogued as COSV101275592; called by muse, mutect2, varscan2
- VCL | c.3131G>T p.R1044L (on ENST00000211998 / NM_014000.3; = p.R976L on NM_003373.4) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV53014973, COSV99280515; called by muse, mutect2, varscan2
- ZBTB18 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.375); catalogued as rs1201132417, COSV100700148; called by muse, mutect2, varscan2
- ZNF74 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100677497; called by muse, mutect2, varscan2
- LYPD4 | c.330C>T p.C110= | Silent (SNP) | VAF 38/138 reads (28%) | catalogued as COSV100419427; called by muse, mutect2, varscan2
- MAP1A | c.7216T>C p.L2406= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs1304078647, COSV100288764; called by muse, mutect2, varscan2
- METTL14 | c.1266T>A p.S422= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV101183404; called by muse, mutect2, varscan2
- USP10 | c.1737A>G p.E579= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV99551497; called by muse, mutect2, varscan2
- WNT7B | c.207C>T p.G69= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV100255023; called by muse, mutect2, varscan2
- ZNF292 | c.264C>G p.A88= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV100370533; called by muse, mutect2, varscan2
